CCDI case PBBKPY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/590ddafa-d7f8-4edf-bb7d-d67d30f9c87c

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 9.8 years (3,573 days).

Biospecimens (3 samples)
- Sample 0DB12A: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DB12I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DB12P: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
